Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7298, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7298-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Surgical Pathology Report

[REDACTED]

Received:
Reported:

Physician(s):
Phy Locat

=====

CLINICAL HISTORY

[REDACTED] old woman has headaches and visual disturbances for about 2 weeks. On clinical examination, retinal hemorrhages. On imaging studies, large left temporal parietal, intra-axial brain tumor with questionable hemorrhage or calcium deposits. There are associated edema and heterogenous enhancement.

OPERATIVE DIAGNOSES
Not Given

Operation/Specimen: A: Brain, left temporal tumor, biopsy
B: Brain, left temporal tumor, biopsy

PATHOLOGICAL DIAGNOSIS:
A and B. Brain, left temporal parietal, excisional biopsies and resection:
Anaplastic astrocytoma. MIB-1 proliferation index: 15%.
See comment.

COMMENT
Specimen A is small fragments of a glial neoplastic proliferation with nuclear anaplasia and mitotic figures sprinkled throughout the tumor.
Specimen B is large fragments of brain infiltrated and effaced by a similar glial proliferation with an astrocyte phenotype, marked nuclear anaplasia, and brisk mitotic activity.
The MIB-1 proliferation index is about 15%. There is focal (cortical) microvascular calcification, but microvascular cellular proliferation and necrosis are inconspicuous.
The morphological findings are interpreted as an anaplastic glioma,

[page 2 of 3]
predominantly astrocytoma, with perhaps a minor oligodendroglial component
(part A).

=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] Molecular Pathology laboratory as required by [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

Brain, left temporal tumor, touch prep and smears: Glioma, atypical oligodendroglioma). [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

Received fresh, several fragments, 0.7 cm. in aggregate. Semi firm, grayish-pink. In total, A1 and A2.

[page 3 of 3]
B.
SPECIMEN: Left temporal tumor.
FIXATIVE: None.
GENERAL: A 3.0 x 2.5 x 0.9 cm. aggregate of soft dusky red to gray-tan brain tissue. Sectioned.
SECTIONS: B1-B3, all submitted.

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates moderate glial fibrillogenesis by the neoplastic cells. About 25% of the neoplastic cells over express the p53 protein. The CD34 depicts a microvasculature without microvascular cellular proliferation. In the more active areas, the MIB-1 proliferation index is about 15%.

These findings support a diagnosis of anaplastic astrocytoma.

Billing Fee Code(s):

Histo Data

Part A: Brain, left temporal tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
CD34-DA x 1	2		
mGFAP-DA x 1	2		
H/E x 1	2		
MIB1-DA x 1	2		
P53DO7 x 1	2		
x 1	(none)		

Part B: Brain, left temporal tumor, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
H/E x 1	2		
CD34-DA x 1	3		
mGFAP-DA x 1	3		
H/E x 1	3		
MIB1-DA x 1	3		
P53DO7 x 1	3		

*** End of Report ***

Source: NCI Genomic Data Commons file f6b23bfd-23f6-4ad7-ba54-e303acd2071d (TCGA-DU-7298.14BF3D59-284E-40D0-BA0B-0F88815A8A3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).